Somatic mutation profile of cancer-model specimen HCM-CSHL-0368-D37-85P (3D Organoid; aliquot HCM-CSHL-0368-D37-85P-01D-A78T-36), derived from the premalignant tumor of HCMI case HCM-CSHL-0368-D37, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Noninfiltrating intraductal papillary adenocarcinoma; Tissue or organ of origin: Gallbladder; AJCC pathologic stage: Stage 0; Tumor grade: GB; Age at diagnosis: 65.9 years (24,078 days).
Specimen HCM-CSHL-0368-D37-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da8fe5e2-e71d-495c-8582-4a3fb22c464e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0368-D37-10A (Blood Derived Normal), aliquot HCM-CSHL-0368-D37-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/210cce21-ad68-4be8-a69e-97198b1c8e52

The open-access MAF lists 314 somatic variants for this specimen: 204 protein-altering or splice-affecting, 74 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 181, Silent 74, Nonsense Mutation 16, Intron 13, 5'UTR 8, RNA 6, 3'UTR 5, Frame Shift Del 4, 5'Flank 3, Frame Shift Ins 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 44/339 reads (13%) | catalogued as rs145945630, CM086465, COSV57336675; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 230/504 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 341/551 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AC011448.1 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52277079; called by muse, mutect2, varscan2
- ADAMTS3 | c.2617C>T p.R873C | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759621311, COSV54392009; called by muse, mutect2, varscan2
- ANKRD27 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 92/268 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs201398434, COSV60131683; called by muse, mutect2, varscan2
- ANOS1 | c.1841C>T p.S614F | Missense Mutation (SNP) | VAF 70/126 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV99391367; called by muse, mutect2, varscan2
- ANXA8 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 165/709 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1427838234; called by muse, mutect2, varscan2
- ARC | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.13); catalogued as rs373236073; called by muse, mutect2, varscan2
- ARNT | c.875G>C p.G292A | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1337983076; called by muse, mutect2, varscan2
- ARPC5 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54171386, COSV54172345; called by muse, mutect2, varscan2
- ASPM | c.6852_6855del p.L2285Rfs*6 | Frame Shift Del (DEL) | VAF 68/248 reads (27%) | catalogued as rs587783259; called by mutect2, pindel, varscan2
- ATL3 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 54/412 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as rs781024290; called by muse, mutect2, varscan2
- ATP13A3 | c.3383C>G p.S1128C | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.434); catalogued as COSV55464512; called by muse, mutect2, varscan2
- B4GALNT4 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as COSV100327832; called by muse, mutect2, varscan2
- BCLAF1 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | catalogued as rs759289578, COSV62145348; called by muse, mutect2, varscan2
- BCOR | c.867G>A p.W289* | Nonsense Mutation (SNP) | VAF 157/158 reads (99%) | catalogued as COSV60707678; called by muse, mutect2, varscan2
- BLOC1S5 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 123/404 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.873); catalogued as rs1409220472; called by muse, mutect2, varscan2
- C12orf43 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 75/507 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV56566313, COSV56566816; called by muse, mutect2, varscan2
- C1QB | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 86/260 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as rs770317321, COSV59245894; called by muse, mutect2, varscan2
- CADPS2 | c.3221G>A p.R1074H | Missense Mutation (SNP) | VAF 91/246 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs181462771; called by muse, mutect2, varscan2
- CALCR | c.1042G>T p.E348* (on ENST00000649521 / NM_001164737.2; = p.E332* on NM_001742.4) | Nonsense Mutation (SNP) | VAF 121/393 reads (31%) | catalogued as COSV64008352; called by muse, mutect2, varscan2
- CCM2L | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 172/517 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as rs573320466; called by muse, mutect2, varscan2
- CDC14C | c.349C>T p.R117C (on ENST00000428251; = p.R10C on NM_152627.3) | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs746551948; called by muse, mutect2, varscan2
- CDC37L1 | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.088); catalogued as COSV101116447; called by muse, mutect2, varscan2
- CELSR1 | c.6262C>T p.R2088* | Nonsense Mutation (SNP) | VAF 73/147 reads (50%) | catalogued as COSV99419456; called by muse, mutect2, varscan2
- CHAF1A | c.2540C>T p.S847L | Missense Mutation (SNP) | VAF 92/196 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs749929809, COSV56670982; called by muse, mutect2, varscan2
- CHRM2 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 214/419 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748172206, COSV57765468, COSV57787501; called by muse, mutect2, varscan2
- CLEC14A | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 201/444 reads (45%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.547); catalogued as COSV60562785; called by muse, mutect2, varscan2
- CLK2 | c.1447C>T p.R483W (on ENST00000368361 / NM_001294339.2; = p.R482W on NM_003993.4) | Missense Mutation (SNP) | VAF 99/406 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs200444017, COSV100226613; called by muse, mutect2, varscan2
- CNPY3 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs963890660; called by muse, varscan2
- COL3A1 | c.3607G>A p.A1203T | Missense Mutation (SNP) | VAF 120/234 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.038); catalogued as rs550665335, CM1512473, COSV58595485, COSV58597783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPNE7 | c.1405G>A p.V469M | Missense Mutation (SNP) | VAF 131/364 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs368685442; called by muse, mutect2, varscan2
- CR1 | c.3799C>T p.H1267Y | Missense Mutation (SNP) | VAF 126/440 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV100887387; called by muse, mutect2, varscan2
- DUSP22 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 82/456 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs1204467799; called by muse, mutect2, varscan2
- EEF1A1 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100303411, COSV58550679; called by muse, mutect2, varscan2
- ERBB3 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 231/735 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV57248254; called by muse, mutect2, varscan2
- ESR1 | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 179/358 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as COSV52790184; called by muse, mutect2, varscan2
- FBXO4 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 108/247 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs376695334; called by muse, mutect2, varscan2
- FES | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373409188; called by muse, mutect2
- FLNC | c.6310G>A p.E2104K | Missense Mutation (SNP) | VAF 96/579 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs753069149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GAA | c.1870C>T p.L624F | Missense Mutation (SNP) | VAF 98/803 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs764377962; called by muse, mutect2, varscan2
- GABBR1 | c.1591G>A p.G531S | Missense Mutation (SNP) | VAF 233/336 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1443264821; called by muse, mutect2, varscan2
- GAPDH | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 121/381 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.06); catalogued as COSV57522062; called by muse, mutect2, varscan2
- GDI2 | c.1238C>T p.T413M | Missense Mutation (SNP) | VAF 104/226 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1010582641; called by muse, mutect2, varscan2
- GRK7 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 88/279 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99379718; called by muse, mutect2, varscan2
- HPSE | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as rs1293803268; called by muse, mutect2, varscan2
- ICE1 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.099); catalogued as COSV56821628; called by muse, mutect2, varscan2
- IMPG1 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 91/264 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as rs774566521, COSV63113184; called by muse, mutect2, varscan2
- KCNMA1 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 9/265 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs1257184004; called by muse, mutect2
- KIAA0825 | c.2266G>C p.D756H | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV56959247; called by muse, mutect2, varscan2
- KMT2D | c.13936G>T p.E4646* | Nonsense Mutation (SNP) | VAF 36/270 reads (13%) | catalogued as COSV56471509, COSV56485227; called by muse, mutect2, varscan2
- KRT12 | c.798C>A p.N266K | Missense Mutation (SNP) | VAF 261/792 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1377759568; called by muse, mutect2, varscan2
- KSR2 | c.2688G>C p.Q896H | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.511); catalogued as COSV56681417; called by muse, mutect2, varscan2
- LAMA3 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 446/916 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs539451824, COSV58066561; called by muse, varscan2
- LRRC74A | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 108/321 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs779195574; called by muse, mutect2, varscan2
- LRTM2 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs919752328; called by muse, mutect2
- MAGEB6 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 120/120 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as rs750400525, COSV66871849; called by muse, mutect2, varscan2
- MAP2K7 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 44/342 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185925179, COSV67607748, COSV67607971; called by muse, mutect2, varscan2
- MC3R | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 257/538 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.192); catalogued as rs767240745, COSV54762982; called by muse, mutect2, varscan2
- MED21 | c.10C>G p.R4G | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs1216682786; called by muse, varscan2
- MICALL2 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 95/298 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs894754271; called by muse, mutect2, varscan2
- MIER2 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 87/347 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53398974; called by muse, mutect2, varscan2
- MYO18B | c.3659C>T p.P1220L | Missense Mutation (SNP) | VAF 272/604 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs780088091; called by muse, mutect2, varscan2
- MYO1G | c.2581C>T p.Q861* | Nonsense Mutation (SNP) | VAF 51/151 reads (34%) | catalogued as rs139568291; called by muse, mutect2, varscan2
- NEDD4 | c.1753G>A p.E585K (on ENST00000508342 / NM_001284338.1; = p.E166K on NM_006154.4) | Missense Mutation (SNP) | VAF 68/277 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs779539984; called by muse, mutect2, varscan2
- NKAPL | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as rs1433579405, COSV59196862; called by muse, mutect2
- NRXN2 | c.3491G>A p.R1164H | Missense Mutation (SNP) | VAF 184/529 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV55452750; called by muse, mutect2, varscan2
- OR10A2 | c.159A>C p.L53F | Missense Mutation (SNP) | VAF 226/490 reads (46%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV56299938; called by muse, mutect2
- OR10G7 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 134/457 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.167); catalogued as rs760167866; called by muse, mutect2, varscan2
- PANX2 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.998); catalogued as COSV50296144; called by muse, mutect2, varscan2
- PCDH8 | c.2609G>A p.R870Q | Missense Mutation (SNP) | VAF 135/249 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); catalogued as rs1407354737; called by muse, mutect2, varscan2
- PCDHA3 | c.458C>A p.S153* | Nonsense Mutation (SNP) | VAF 174/399 reads (44%) | catalogued as COSV65365425; called by muse, mutect2, varscan2
- PCSK4 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 51/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780993747; called by muse, mutect2, varscan2
- PDPR | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 90/586 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753821381; called by muse, mutect2, varscan2
- PLEKHG1 | c.2401C>A p.Q801K | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV62046652; called by muse, mutect2, varscan2
- PRUNE2 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV65046606; called by muse, mutect2, varscan2
- PTPN2 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 152/283 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs1254988153; called by muse, mutect2, varscan2
- PTPRT | c.2857C>T p.R953* | Nonsense Mutation (SNP) | VAF 9/130 reads (7%) | catalogued as COSV99049486; called by muse, mutect2
- RBBP5 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 44/174 reads (25%) | catalogued as COSV52706459; called by muse, mutect2, varscan2
- RCC1L | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 240/425 reads (56%) | SIFT tolerated (0.49); PolyPhen benign (0.374); catalogued as rs781910319; called by muse, mutect2
- RERE | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 189/332 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1157900037, COSV61945030; called by muse, mutect2, varscan2
- RNPEPL1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 182/563 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs139059683, COSV54374143; called by muse, mutect2, varscan2
- RRAS | c.241+3G>A | Splice Region (SNP) | VAF 82/280 reads (29%) | catalogued as rs766535520; called by muse, mutect2, varscan2
- SEPTIN14 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs778731243, COSV66428415; called by muse, mutect2, varscan2
- SIRPB1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 54/475 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.186); catalogued as rs565483001; called by muse, mutect2, varscan2
- SIX4 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99382474; called by muse, mutect2, varscan2
- SLC3A1 | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.114); catalogued as CM1111545; called by muse, mutect2, varscan2
- SPTA1 | c.6544G>C p.D2182H | Missense Mutation (SNP) | VAF 40/476 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs187749998, COSV63753555; called by muse, mutect2
- SPTA1 | c.3139C>T p.R1047* | Nonsense Mutation (SNP) | VAF 139/691 reads (20%) | catalogued as COSV63755204, COSV63757673; called by muse, varscan2
- SSC5D | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.104); catalogued as rs758499359; called by muse, mutect2, varscan2
- SVOPL | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.69); catalogued as rs139868586; called by muse, mutect2, varscan2
- TCERG1 | c.2476C>T p.R826C | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755170489, COSV57034377; called by muse, mutect2, varscan2
- TELO2 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 76/230 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs148873855; called by muse, mutect2, varscan2
- TEPSIN | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 40/458 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs767337646, COSV56142744; called by muse, mutect2
- TEX15 | c.7483G>A p.D2495N (on ENST00000256246; = p.D2878N on NM_001350162.2) | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV56355484; called by muse, mutect2, varscan2
- THSD7B | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 116/420 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.492); catalogued as COSV55659425, COSV55734401; called by muse, mutect2, varscan2
- TINAGL1 | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200401314, COSV54698792; called by muse, mutect2, varscan2
- TLL1 | c.2647C>T p.H883Y | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.634); catalogued as rs1005207244; called by muse, mutect2, varscan2
- TRAPPC8 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV51972041; called by muse, mutect2, varscan2
- TRAPPC9 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 262/580 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1184876472, COSV66900182; called by muse, mutect2, varscan2
- U2SURP | c.2419C>G p.Q807E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV101204512; called by muse, varscan2
- U2SURP | c.2501C>G p.S834C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); catalogued as rs759670533; called by muse, varscan2
- UBR4 | c.10997C>T p.S3666L | Missense Mutation (SNP) | VAF 38/325 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100921439; called by muse, mutect2, varscan2
- WDR6 | c.2288C>T p.S763L | Missense Mutation (SNP) | VAF 123/407 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1202321100, COSV100556406, COSV58243966, COSV58244167; called by muse, mutect2, varscan2
- ZMYM1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.111); catalogued as COSV63252992; called by muse, mutect2, varscan2
- ZMYND19 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 102/328 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs779910825, COSV53812243; called by mutect2, varscan2
- ZNF721 | c.424C>T p.Q142* (on ENST00000338977; = p.Q154* on NM_133474.4) | Nonsense Mutation (SNP) | VAF 228/477 reads (48%) | catalogued as COSV100167829; called by muse, mutect2, varscan2
- AC084756.2 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- ADGRV1 | c.10855G>C p.E3619Q | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ALMS1 | c.2282C>A p.S761Y | Missense Mutation (SNP) | VAF 162/496 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ANKRD42 | c.448C>G p.L150V | Missense Mutation (SNP) | VAF 69/455 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AP1G2 | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARFGEF1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASAP3 | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ATPAF1 | c.802G>C p.E268Q (on ENST00000574428; = p.E291Q on NM_022745.4) | Missense Mutation (SNP) | VAF 104/325 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- BRINP2 | c.1150A>G p.K384E | Missense Mutation (SNP) | VAF 189/922 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BTBD8 | c.4694A>T p.D1565V (on ENST00000636805 / NM_001376131.1; = p.D1052V on NM_015237.4) | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C6orf132 | c.3079G>T p.G1027C | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CARMIL2 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- CCDC191 | c.614G>A p.R205K | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CDH12 | c.1210G>T p.G404C | Missense Mutation (SNP) | VAF 197/372 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK17 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK5 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 73/472 reads (15%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CFAP61 | c.2854G>A p.D952N | Missense Mutation (SNP) | VAF 109/229 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- CIITA | c.2009G>A p.R670K | Missense Mutation (SNP) | VAF 265/845 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- COL7A1 | c.4454C>T p.P1485L | Missense Mutation (SNP) | VAF 205/643 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); called by muse, varscan2
- CSTL1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CYLC1 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 52/52 reads (100%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- DLG5 | c.3830C>A p.P1277Q | Missense Mutation (SNP) | VAF 109/341 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- EARS2 | c.146T>G p.L49W | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ECHS1 | c.129G>C p.K43N | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- ELP4 | c.1009G>A p.E337K (on ENST00000350638; = p.E336K on NM_019040.5) | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- EPHB6 | c.2530G>T p.D844Y | Missense Mutation (SNP) | VAF 271/567 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM209B | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 195/554 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FRMD7 | c.212A>T p.K71M | Missense Mutation (SNP) | VAF 103/103 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GTSE1 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- HEATR5A | c.1696C>G p.L566V | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- HECTD4 | c.6583A>G p.T2195A | Missense Mutation (SNP) | VAF 106/199 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- HELQ | c.2120G>C p.R707T | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV3-35 | c.318G>T p.R106S | Missense Mutation (SNP) | VAF 131/247 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- INTS9 | c.1931G>C p.R644T | Missense Mutation (SNP) | VAF 95/526 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- KANSL1 | c.1004del p.L335Wfs*4 | Frame Shift Del (DEL) | VAF 97/465 reads (21%) | called by mutect2, pindel, varscan2
- KDM4A | c.1413dup p.L472Tfs*6 | Frame Shift Ins (INS) | VAF 22/65 reads (34%) | called by mutect2, pindel, varscan2
- KLF5 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- KLF5 | c.408G>C p.M136I | Missense Mutation (SNP) | VAF 128/421 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KMT2D | c.14008G>C p.E4670Q | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KPNA3 | c.1457C>G p.S486C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- LCA5L | c.608A>C p.H203P | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRSAM1 | c.1297T>C p.S433P | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- MAML3 | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 163/467 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MED14 | c.2910T>G p.N970K | Missense Mutation (SNP) | VAF 58/58 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- MTUS1 | c.3133G>T p.E1045* (on ENST00000262102 / NM_001363061.1; = p.E211* on NM_020749.4) | Nonsense Mutation (SNP) | VAF 42/236 reads (18%) | called by muse, mutect2, varscan2
- MYCBP2 | c.9433A>G p.I3145V (on ENST00000357337; = p.I3183V on NM_015057.5) | Missense Mutation (SNP) | VAF 256/256 reads (100%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- MYO9B | c.4244C>T p.T1415M | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NLRP9 | c.2494G>C p.E832Q | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- NR1H4 | c.1155del p.S385Rfs*5 (on ENST00000551379 / NM_001206993.2; = p.S371Rfs*5 on NM_005123.4) | Frame Shift Del (DEL) | VAF 71/173 reads (41%) | called by mutect2, pindel, varscan2
- NR4A1 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- NUDT10 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 88/137 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- NUP58 | c.389C>G p.S130* | Nonsense Mutation (SNP) | VAF 96/217 reads (44%) | called by muse, mutect2, varscan2
- OR14K1 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 196/625 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR8G5 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 12/392 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); called by muse, mutect2
- PCBD2 | c.173G>C p.R58T | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- PCSK7 | c.1299C>A p.H433Q | Missense Mutation (SNP) | VAF 183/385 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PDCL3 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PDE4A | c.1452C>G p.F484L (on ENST00000380702 / NM_001111307.2; = p.F245L on NM_006202.3) | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- PDIA5 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- PHYHD1 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 129/419 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- PLA2G6 | c.810G>A p.M270I | Missense Mutation (SNP) | VAF 38/312 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- PRDM5 | c.1783C>G p.H595D | Missense Mutation (SNP) | VAF 145/253 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PRUNE2 | c.4018G>A p.D1340N | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RIMS1 | c.4558C>T p.L1520F | Missense Mutation (SNP) | VAF 349/690 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RNF214 | c.1297C>G p.Q433E | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- RUSC1 | c.2144C>T p.S715L (on ENST00000368352 / NM_001105203.2; = p.S246L on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/723 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SEMA3C | c.500C>G p.S167C | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLAMF9 | c.257T>C p.V86A | Missense Mutation (SNP) | VAF 29/376 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); called by muse, mutect2
- SLC16A11 | c.878C>T p.A293V (on ENST00000308009; = p.A269V on NM_153357.3) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- SMC3 | c.1808C>T p.T603I | Missense Mutation (SNP) | VAF 105/209 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SPATS2L | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 68/396 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- SPTA1 | c.2462T>A p.L821H | Missense Mutation (SNP) | VAF 48/594 reads (8%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.566); called by muse, mutect2
- SRSF4 | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 48/332 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SSPOP | n.13433-1G>A | Splice Site (SNP) | VAF 126/388 reads (32%) | called by muse, mutect2, varscan2
- STAC | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TAOK1 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TMEM215 | c.557G>C p.R186T | Missense Mutation (SNP) | VAF 199/407 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TPCN1 | c.2307C>A p.S769R | Missense Mutation (SNP) | VAF 123/274 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TPGS1 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRPC6 | c.287_290del p.S96* | Frame Shift Del (DEL) | VAF 28/97 reads (29%) | called by pindel, varscan2
- TTC27 | c.381C>G p.F127L | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- UBR5 | c.7729G>A p.E2577K | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- UBR5 | c.7339G>A p.E2447K | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- VRK1 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- WNK1 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- XPO6 | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 57/331 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ZBTB3 | c.947C>A p.T316N | Missense Mutation (SNP) | VAF 37/414 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.027); called by muse, mutect2
- ZC3H7A | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZFAND5 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ZFP30 | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 130/290 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZMYM6 | c.1392G>C p.K464N | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ZNF264 | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZNF273 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 76/325 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF438 | c.896G>C p.R299T | Missense Mutation (SNP) | VAF 112/364 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- ZNF529 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 99/182 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF581 | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- ACO1 | c.2487C>G p.L829= | Silent (SNP) | VAF 36/258 reads (14%) | catalogued as COSV59381048; called by muse, mutect2
- BAD | c.280C>A p.R94= | Silent (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- CEP350 | c.4146C>T p.L1382= | Silent (SNP) | VAF 72/399 reads (18%) | called by muse, mutect2, varscan2
- CRYBG3 | c.8889G>A p.Q2963= | Silent (SNP) | VAF 46/185 reads (25%) | catalogued as COSV51709624; called by muse, mutect2, varscan2
- CTSS | c.552C>T p.F184= | Silent (SNP) | VAF 50/434 reads (12%) | catalogued as rs587642423, COSV64567021; called by muse, mutect2, varscan2
- CYP11B1 | c.1029G>A p.E343= | Silent (SNP) | VAF 44/441 reads (10%) | catalogued as rs758996199, COSV52828673; called by muse, mutect2, varscan2
- CYTL1 | c.345G>A p.L115= | Silent (SNP) | VAF 116/397 reads (29%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.8250C>G p.T2750= | Silent (SNP) | VAF 151/555 reads (27%) | called by muse, mutect2, varscan2
- DYNC2I2 | c.1461T>C p.C487= | Silent (SNP) | VAF 175/595 reads (29%) | called by muse, mutect2, varscan2
- EBF3 | c.1083G>A p.Q361= (on ENST00000355311 / NM_001375392.1; = p.Q352= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 86/398 reads (22%) | called by muse, mutect2, varscan2
- EIF3A | c.2964C>T p.S988= | Silent (SNP) | VAF 78/466 reads (17%) | catalogued as COSV64960682; called by muse, mutect2, varscan2
- ELFN1 | c.780C>G p.V260= | Silent (SNP) | VAF 161/305 reads (53%) | catalogued as COSV101300249; called by muse, mutect2, varscan2
- ELP6 | c.249C>T p.F83= | Silent (SNP) | VAF 26/184 reads (14%) | called by muse, mutect2, varscan2
- FAM53B | c.294C>T p.I98= | Silent (SNP) | VAF 42/253 reads (17%) | called by muse, mutect2, varscan2
- FASN | c.3471G>A p.L1157= | Silent (SNP) | VAF 77/674 reads (11%) | called by muse, mutect2, varscan2
- FCRL3 | c.1395G>A p.V465= | Silent (SNP) | VAF 19/233 reads (8%) | called by muse, mutect2
- FDX2 | c.516C>T p.I172= | Silent (SNP) | VAF 53/360 reads (15%) | catalogued as rs1394254913; called by muse, mutect2, varscan2
- FOXE1 | c.852C>T p.P284= | Silent (SNP) | VAF 103/274 reads (38%) | called by muse, mutect2, varscan2
- GNAS | c.1584C>G p.L528= | Silent (SNP) | VAF 96/599 reads (16%) | catalogued as rs1260949887; called by muse, mutect2, varscan2
- GRIP1 | c.1650G>A p.T550= (on ENST00000359742 / NM_001379345.1; = p.T498= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 65/379 reads (17%) | catalogued as rs1369161246, COSV54022542, COSV54038894; called by muse, mutect2, varscan2
- HS3ST4 | c.1284G>A p.L428= | Silent (SNP) | VAF 138/621 reads (22%) | catalogued as rs770057072; called by muse, mutect2, varscan2
- IGHA2 | c.63C>T p.N21= | Silent (SNP) | VAF 113/569 reads (20%) | catalogued as rs781784169; called by muse, mutect2, varscan2
- IQCN | c.3156C>T p.I1052= | Silent (SNP) | VAF 182/358 reads (51%) | catalogued as rs576833251; called by muse, mutect2, varscan2
- ITGA8 | c.78G>A p.A26= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs1015951222; called by muse, mutect2
- ITGA9 | c.663C>T p.I221= | Silent (SNP) | VAF 34/279 reads (12%) | called by muse, mutect2, varscan2
- KCNQ3 | c.1524C>T p.I508= | Silent (SNP) | VAF 47/142 reads (33%) | catalogued as rs761576731; called by muse, mutect2, varscan2
- KCTD8 | c.597C>T p.G199= | Silent (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- KIF2B | c.279G>A p.P93= | Silent (SNP) | VAF 29/289 reads (10%) | catalogued as rs769032021, COSV52129526; called by muse, mutect2
- KIRREL2 | c.48C>T p.F16= | Silent (SNP) | VAF 71/230 reads (31%) | called by muse, mutect2, varscan2
- KRTAP26-1 | c.381G>A p.P127= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as rs201629624, COSV62128773; called by muse, mutect2, varscan2
- L3MBTL4 | c.1050G>A p.P350= | Silent (SNP) | VAF 79/182 reads (43%) | catalogued as rs267605237; called by muse, mutect2, varscan2
- LAMC2 | c.3207G>A p.T1069= | Silent (SNP) | VAF 88/1012 reads (9%) | catalogued as rs748282223, COSV99917451; called by muse, mutect2
- LRRC19 | c.234C>G p.L78= | Silent (SNP) | VAF 29/98 reads (30%) | called by muse, mutect2, varscan2
- MAP3K9 | c.2520C>T p.I840= (on ENST00000554752 / NM_001284230.1; = p.I854= on NM_033141.4) | Silent (SNP) | VAF 43/144 reads (30%) | catalogued as rs541892601; called by muse, mutect2, varscan2
- MAST2 | c.3369C>G p.V1123= | Silent (SNP) | VAF 39/481 reads (8%) | called by muse, mutect2
- MFSD4A | c.1065C>T p.F355= | Silent (SNP) | VAF 165/420 reads (39%) | catalogued as COSV65657177; called by muse, mutect2, varscan2
- MRPS30 | c.552C>T p.L184= | Silent (SNP) | VAF 91/161 reads (57%) | catalogued as rs1449062417; called by muse, mutect2, varscan2
- MYO3B | c.3606G>T p.G1202= | Silent (SNP) | VAF 56/134 reads (42%) | called by muse, mutect2, varscan2
- NSMCE2 | c.399G>A p.L133= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as rs1466906535; called by muse, mutect2, varscan2
- NXPE2 | c.699G>A p.L233= | Silent (SNP) | VAF 79/257 reads (31%) | called by muse, mutect2, varscan2
- OR2AT4 | c.126C>T p.L42= | Silent (SNP) | VAF 141/396 reads (36%) | catalogued as COSV100532430; called by muse, mutect2, varscan2
- PAK3 | c.84C>T p.L28= | Silent (SNP) | VAF 147/240 reads (61%) | called by muse, mutect2, varscan2
- PCDHGA7 | c.1458G>A p.Q486= | Silent (SNP) | VAF 105/375 reads (28%) | catalogued as rs1226263341; called by muse, mutect2, varscan2
- PCED1B | c.699T>C p.N233= | Silent (SNP) | VAF 45/280 reads (16%) | called by muse, mutect2, varscan2
- PNPLA3 | c.657C>T p.L219= | Silent (SNP) | VAF 202/416 reads (49%) | called by muse, mutect2, varscan2
- PPWD1 | c.1113G>C p.L371= | Silent (SNP) | VAF 26/135 reads (19%) | called by muse, mutect2, varscan2
- PTPRH | c.3069C>T p.G1023= | Silent (SNP) | VAF 87/176 reads (49%) | catalogued as rs369061024; called by muse, mutect2, varscan2
- PTX4 | c.921C>T p.S307= (on ENST00000447419 / NM_001328608.2; = p.S302= on NM_001013658.1) | Silent (SNP) | VAF 60/366 reads (16%) | catalogued as rs761033779, COSV53517374; called by muse, mutect2, varscan2
- PZP | c.3346C>T p.L1116= | Silent (SNP) | VAF 42/253 reads (17%) | called by muse, mutect2, varscan2
- RENBP | c.1140C>G p.L380= | Silent (SNP) | VAF 80/115 reads (70%) | called by muse, mutect2, varscan2
- RPL3 | c.48C>T p.F16= | Silent (SNP) | VAF 132/301 reads (44%) | called by muse, mutect2, varscan2
- SCN5A | c.2007C>T p.L669= | Silent (SNP) | VAF 40/301 reads (13%) | called by muse, mutect2, varscan2
- SIM1 | c.663C>T p.A221= | Silent (SNP) | VAF 58/370 reads (16%) | catalogued as COSV53495966, COSV53497316; called by muse, mutect2, varscan2
- SIRPB1 | c.729C>G p.A243= | Silent (SNP) | VAF 54/470 reads (11%) | called by muse, mutect2, varscan2
- SLC6A2 | c.462C>T p.V154= | Silent (SNP) | VAF 22/755 reads (3%) | catalogued as rs956114096; called by muse, mutect2
- SMPD4 | c.2502C>T p.V834= (on ENST00000409031 / NM_017951.4; = p.V805= on NM_017751.4) | Silent (SNP) | VAF 203/610 reads (33%) | catalogued as rs767644066, COSV100302854; called by muse, mutect2, varscan2
- SNED1 | c.1428C>T p.N476= | Silent (SNP) | VAF 175/380 reads (46%) | catalogued as rs368791923; called by muse, mutect2, varscan2
- SPPL2A | c.45C>A p.L15= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as rs1305473823; called by muse, mutect2, varscan2
- SSC5D | c.1041C>T p.C347= | Silent (SNP) | VAF 99/221 reads (45%) | catalogued as rs1336519069, COSV101046504; called by muse, mutect2, varscan2
- ST8SIA4 | c.288A>T p.S96= | Silent (SNP) | VAF 85/272 reads (31%) | called by muse, mutect2, varscan2
- STAG1 | c.2724G>A p.L908= | Silent (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- SYBU | c.465C>T p.G155= (on ENST00000276646 / NM_001099754.2; = p.G154= on NM_017786.6) | Silent (SNP) | VAF 97/320 reads (30%) | catalogued as rs954713147, COSV52615504; called by muse, mutect2, varscan2
- TBC1D8 | c.2067C>T p.F689= | Silent (SNP) | VAF 127/413 reads (31%) | called by muse, mutect2, varscan2
- TDRD1 | c.3246G>A p.Q1082= | Silent (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
- TET1 | c.4887G>A p.Q1629= | Silent (SNP) | VAF 35/139 reads (25%) | called by muse, mutect2, varscan2
- TMIGD1 | c.64C>T p.L22= | Silent (SNP) | VAF 54/86 reads (63%) | called by muse, mutect2, varscan2
- TOP3B | c.903G>C p.L301= | Silent (SNP) | VAF 94/343 reads (27%) | called by muse, mutect2, varscan2
- TRAPPC2L | c.243C>T p.V81= | Silent (SNP) | VAF 91/479 reads (19%) | catalogued as rs752232543; called by muse, mutect2, varscan2
- ULBP1 | c.249C>G p.V83= | Silent (SNP) | VAF 42/291 reads (14%) | called by muse, mutect2, varscan2
- WDR38 | c.198G>A p.V66= | Silent (SNP) | VAF 67/212 reads (32%) | called by muse, mutect2, varscan2
- WNT2 | c.42G>A p.L14= | Silent (SNP) | VAF 118/232 reads (51%) | catalogued as COSV99625671; called by muse, mutect2, varscan2
- XRCC3 | c.993G>T p.T331= | Silent (SNP) | VAF 154/482 reads (32%) | called by muse, mutect2, varscan2
- ZNF529 | c.609A>G p.Q203= | Silent (SNP) | VAF 49/86 reads (57%) | catalogued as rs200704899; called by muse, mutect2, varscan2
- ZNF791 | c.1152C>T p.Y384= | Silent (SNP) | VAF 53/99 reads (54%) | catalogued as rs182973227; called by muse, mutect2, varscan2
- A2ML1 | c.1477-238C>T | Intron (SNP) | VAF 41/226 reads (18%) | called by muse, mutect2, varscan2
- AC103993.1 | n.97A>T | RNA (SNP) | VAF 74/241 reads (31%) | called by muse, mutect2, varscan2
- ACTN4 | c.*166T>C | 3'UTR (SNP) | VAF 154/315 reads (49%) | catalogued as rs779624869; called by mutect2, varscan2
- ADH5P5 | chr5:23977834 C>T | 5'Flank (SNP) | VAF 31/132 reads (23%) | called by muse, mutect2, varscan2
- ALG3 | chr3:184249260 C>T | 5'Flank (SNP) | VAF 86/261 reads (33%) | catalogued as rs768711978; called by muse, mutect2, varscan2
- BAD | c.*141C>G | 3'UTR (SNP) | VAF 22/84 reads (26%) | called by muse, varscan2
- CRIP3 | chr6:43305752 C>T | 3'Flank (SNP) | VAF 45/276 reads (16%) | catalogued as COSV99240359; called by muse, mutect2, varscan2
- GABRG3 | c.712+14G>A | Intron (SNP) | VAF 53/148 reads (36%) | called by muse, mutect2, varscan2
- GRK5 | c.*231G>A | 3'UTR (SNP) | VAF 20/334 reads (6%) | called by muse, mutect2
- IER3IP1 | c.-20C>T | 5'UTR (SNP) | VAF 150/453 reads (33%) | catalogued as rs1037936721; called by muse, mutect2, varscan2
- KIF16B | c.3498+3300C>G | Intron (SNP) | VAF 27/194 reads (14%) | called by muse, mutect2, varscan2
- MSC-AS1 | n.344C>T | RNA (SNP) | VAF 192/433 reads (44%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.899C>T | RNA (SNP) | VAF 277/615 reads (45%) | catalogued as rs1457579821; called by muse, mutect2, varscan2
- PATZ1 | chr22:31347077 G>T | 5'Flank (SNP) | VAF 46/202 reads (23%) | called by muse, mutect2, varscan2
- PEX19 | c.816+32T>A | Intron (SNP) | VAF 340/527 reads (65%) | called by muse, mutect2, varscan2
- PPDPFL | c.-11C>T | 5'UTR (SNP) | VAF 44/130 reads (34%) | catalogued as rs747140610, COSV57462675; called by muse, mutect2, varscan2
- PRR29 | c.*113C>T | 3'UTR (SNP) | VAF 202/1011 reads (20%) | catalogued as rs1026103130; called by muse, mutect2, varscan2
- PRSS33 | c.-9G>C | 5'UTR (SNP) | VAF 40/219 reads (18%) | called by muse, mutect2, varscan2
- PSG4 | c.65-608C>T | Intron (SNP) | VAF 129/273 reads (47%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1642G>A | RNA (SNP) | VAF 78/128 reads (61%) | called by muse, mutect2, varscan2
- SAMD4A | c.197-16379C>A | Intron (SNP) | VAF 62/172 reads (36%) | called by muse, mutect2, varscan2
- SGSM3 | c.2172+73G>A | Intron (SNP) | VAF 32/238 reads (13%) | catalogued as COSV50651911; called by muse, mutect2, varscan2
- SLC2A14 | c.-59G>C | 5'UTR (SNP) | VAF 44/84 reads (52%) | called by muse, mutect2, varscan2
- SLC7A7 | c.-180-141G>A | Intron (SNP) | VAF 220/512 reads (43%) | catalogued as rs1288257184; called by muse, mutect2, varscan2
- SPAG6 | c.-13C>T | 5'UTR (SNP) | VAF 69/167 reads (41%) | catalogued as rs909856066; called by muse, mutect2, varscan2
- SPDL1 | c.1670+82C>G | Intron (SNP) | VAF 84/275 reads (31%) | called by muse, mutect2, varscan2
- SPPL2B | c.956+294C>T | Intron (SNP) | VAF 162/552 reads (29%) | catalogued as rs370421065; called by muse, mutect2, varscan2
- SSPOP | n.11684C>T | RNA (SNP) | VAF 108/223 reads (48%) | called by muse, mutect2, varscan2
- SSPOP | n.13078G>A | RNA (SNP) | VAF 76/428 reads (18%) | catalogued as rs748253553; called by muse, mutect2, varscan2
- STRA6 | c.-15-161G>C | Intron (SNP) | VAF 80/360 reads (22%) | called by muse, mutect2, varscan2
- TBC1D23 | c.-8C>G | 5'UTR (SNP) | VAF 70/224 reads (31%) | called by muse, mutect2, varscan2
- TBCD | c.3565-9C>G | Intron (SNP) | VAF 180/597 reads (30%) | called by muse, mutect2, varscan2
- TENT5A | c.-242A>T | 5'UTR (SNP) | VAF 167/361 reads (46%) | called by muse, mutect2, varscan2
- TMIGD3 | c.215-614C>T | Intron (SNP) | VAF 13/55 reads (24%) | catalogued as rs1010308248; called by muse, mutect2, varscan2
- USP10 | c.-39C>T | 5'UTR (SNP) | VAF 83/442 reads (19%) | catalogued as rs544515816; called by muse, mutect2, varscan2
- ZDHHC20 | c.*1579C>G | 3'UTR (SNP) | VAF 65/196 reads (33%) | called by muse, mutect2, varscan2
